Somatic mutation profile of tumor specimen ALCH-B1VE-TTP1-A (aliquot ALCH-B1VE-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1VE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,076 days).
Specimen ALCH-B1VE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efc03973-9611-4b7e-a08d-b64dc1fb3c9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1VE-NB1-A (Blood Derived Normal), aliquot ALCH-B1VE-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/615b72ff-a715-42d0-a085-63be05b7cf9c

The open-access MAF lists 1,955 somatic variants for this specimen: 1,319 protein-altering or splice-affecting, 402 silent, 234 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,116, Silent 402, Intron 105, Nonsense Mutation 89, Splice Site 44, RNA 38, Frame Shift Del 33, 3'UTR 33, 5'UTR 32, Splice Region 20, 5'Flank 15, Frame Shift Ins 13.

Variants (750 of 1,955; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 29/134 reads (22%) | catalogued as rs121913382, COSV58682685, COSV58683250; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SHH | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886042458, CM041838, CM094632, CM095888; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 76/283 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.9024C>A p.S3008R | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs757980942, COSV71292188; called by muse, mutect2, varscan2
- ABCA6 | c.21C>G p.S7R | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as COSV99446058; called by muse, mutect2, varscan2
- ABCB5 | c.1663C>A p.L555M (on ENST00000404938 / NM_001163941.2; = p.L110M on NM_178559.6) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99328374; called by muse, mutect2, varscan2
- ABL2 | c.2734G>T p.G912C (on ENST00000502732 / NM_007314.4; = p.G897C on NM_005158.5) | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as rs140629135; called by muse, mutect2, varscan2
- AC231657.3 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as rs782710721; called by muse, mutect2, varscan2
- ACBD5 | c.1604G>T p.*535Lext*18 (on ENST00000375888 / NM_001352568.1; = p.*526Lext*18 on NM_145698.5 and 4 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 19/119 reads (16%) | catalogued as COSV65518491; called by muse, mutect2, varscan2
- ACHE | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53814972; called by muse, mutect2, varscan2
- ACSM2B | c.1340G>T p.R447L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs146841908, COSV61658598; called by muse, mutect2, varscan2
- ACTRT1 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as rs367847967, COSV64418970; called by muse, mutect2, varscan2
- ACTRT2 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs768291220, COSV65759034; called by muse, mutect2, varscan2
- ADAMTS20 | c.2550G>T p.W850C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67134904; called by mutect2, varscan2
- ADAMTSL1 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 27/183 reads (15%) | catalogued as COSV52827179; called by muse, mutect2, varscan2
- ADGRG4 | c.5792C>A p.S1931Y | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV99795171; called by muse, varscan2
- AGAP1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 34/300 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs754065305; called by muse, mutect2, varscan2
- AHNAK2 | c.10952C>A p.S3651* | Nonsense Mutation (SNP) | VAF 44/160 reads (28%) | catalogued as COSV60911545; called by muse, mutect2, varscan2
- AKAIN1 | c.128G>C p.R43P | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV71420475; called by muse, mutect2, varscan2
- AKAP11 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1221411587; called by muse, mutect2, varscan2
- ALAD | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52959823; called by muse, varscan2
- ALB | c.1428T>C p.Y476= | Splice Region (SNP) | VAF 18/72 reads (25%) | catalogued as rs757476866, COSV55737675; called by muse, varscan2
- ALS2CL | c.2825G>T p.R942L | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as COSV100015192; called by muse, mutect2, varscan2
- AMER3 | c.1792G>C p.D598H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV58467681; called by muse, mutect2, varscan2
- ANAPC4 | c.2129A>T p.H710L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.034); catalogued as COSV59544848; called by muse, mutect2, varscan2
- ANKRD26 | c.2563G>T p.V855F | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV65774652; called by muse, varscan2
- ANKRD30A | c.1151C>T p.A384V (on ENST00000611781; = p.A328V on NM_052997.2) | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.483); catalogued as rs770792408; called by muse, mutect2, varscan2
- APBA3 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs765983166; called by muse, mutect2, varscan2
- APOBR | c.1618G>T p.V540L (on ENST00000431282; = p.V549L on NM_018690.4) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV60488888; called by muse, mutect2, varscan2
- ARFGEF3 | c.5457C>A p.H1819Q | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV52463623; called by muse, mutect2, varscan2
- ARHGAP31 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 83/164 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51794256; called by muse, mutect2, varscan2
- ARHGEF11 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 87/276 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1265248620; called by muse, mutect2, varscan2
- ASPM | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs761690546; called by muse, mutect2, varscan2
- ATP1B4 | c.671G>A p.R224H (on ENST00000218008 / NM_001142447.3; = p.R220H on NM_012069.5) | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376908557, COSV54312056; called by muse, mutect2, varscan2
- BAAT | c.211A>T p.M71L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs765262834; called by muse, mutect2
- BACH2 | c.911C>A p.A304E | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747189218; called by muse, mutect2
- BPIFB1 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as COSV53609745; called by muse, mutect2, varscan2
- BRF1 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 45/156 reads (29%) | catalogued as COSV100527081; called by muse, mutect2, varscan2
- BRINP2 | c.907T>A p.F303I | Missense Mutation (SNP) | VAF 89/324 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64180580; called by muse, mutect2, varscan2
- C1QTNF4 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100209256; called by muse, mutect2, varscan2
- C1orf94 | c.1448G>T p.G483V (on ENST00000488417 / NM_001134734.2; = p.G293V on NM_032884.5) | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs201753293, COSV64913874; called by muse, mutect2, varscan2
- C2orf81 | c.488dup p.V164Rfs*58 | Frame Shift Ins (INS) | VAF 25/173 reads (14%) | catalogued as rs773631384; called by mutect2, pindel, varscan2
- C4BPA | c.1193C>A p.S398* | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | catalogued as COSV100891234; called by muse, mutect2
- C6orf118 | c.312G>T p.R104S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV57815204; called by muse, mutect2, varscan2
- C8orf34 | c.1555G>C p.A519P | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV61381291; called by muse, mutect2, varscan2
- CA2 | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1453620373; called by muse, mutect2, varscan2
- CABIN1 | c.4702G>T p.A1568S | Missense Mutation (SNP) | VAF 101/386 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV54079306; called by muse, mutect2, varscan2
- CACNA1C | c.5320G>A p.A1774T | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.086); catalogued as rs767425352, COSV59736148; called by muse, mutect2, varscan2
- CADM3 | c.685del p.V229Ffs*8 (on ENST00000368125 / NM_001127173.3; = p.V263Ffs*8 on NM_021189.5) | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | catalogued as COSV63687001; called by pindel, varscan2
- CADPS | c.3106C>A p.P1036T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs868827229; called by muse, mutect2, varscan2
- CAPSL | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV68438932, COSV68439589; called by muse, mutect2, varscan2
- CASP7 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61882927; called by muse, mutect2, varscan2
- CASR | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99949562; called by muse, mutect2, varscan2
- CATSPERE | c.366G>T p.W122C | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100835365; called by muse, mutect2, varscan2
- CCDC168 | c.2809G>A p.V937I | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1412245787; called by muse, mutect2, varscan2
- CCER1 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV62647525; called by muse, mutect2, varscan2
- CCHCR1 | c.335G>C p.R112P | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66161201, COSV66161514; called by muse, varscan2
- CCIN | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV58724854; called by muse, mutect2, varscan2
- CD1C | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV63806924; called by muse, mutect2, varscan2
- CDC42BPB | c.1603C>T p.H535Y | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1566872144; called by muse, mutect2, varscan2
- CDH2 | c.950C>A p.S317* | Nonsense Mutation (SNP) | VAF 14/120 reads (12%) | catalogued as COSV52296678; called by muse, mutect2
- CDH9 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50305218; called by muse, mutect2, varscan2
- CENPF | c.3975G>T p.R1325S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV100871379; called by muse, mutect2, varscan2
- CEP78 | c.1024A>G p.I342V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs765160106; called by mutect2, varscan2
- CHM | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63303198; called by muse, mutect2, varscan2
- CHRNA2 | c.215G>C p.R72P | Missense Mutation (SNP) | VAF 98/324 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs201922955, COSV53558436; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CIC | c.2123G>C p.R708T | Missense Mutation (SNP) | VAF 94/404 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV50549729; called by muse, mutect2, varscan2
- CLVS2 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.79); catalogued as COSV51561523, COSV51566135; called by muse, mutect2, varscan2
- COL15A1 | c.1680G>T p.Q560H | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV66644249; called by muse, mutect2, varscan2
- COL1A2 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 160/377 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM062543; called by muse, mutect2, varscan2
- COL22A1 | c.3072G>C p.K1024N | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV57360051; called by muse, mutect2, varscan2
- COL6A1 | c.1515G>C p.M505I | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV62614872; called by muse, mutect2, varscan2
- COL6A3 | c.5525G>T p.G1842V | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM1413880, COSV55101483; called by muse, mutect2, varscan2
- CPED1 | c.2542C>A p.L848I | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1278152351, COSV60002748, COSV60004550; called by muse, mutect2, varscan2
- CPS1 | c.1688C>A p.P563Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV51810138; called by muse, mutect2, varscan2
- CSMD2 | c.5729C>A p.P1910Q | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.585); catalogued as COSV53910319; called by muse, mutect2, varscan2
- CSMD3 | c.7897G>T p.G2633W (on ENST00000297405 / NM_001363185.1; = p.G2529W on NM_052900.3) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843215; called by muse, mutect2
- CSMD3 | c.6499G>C p.V2167L (on ENST00000297405 / NM_001363185.1; = p.V2063L on NM_052900.3) | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV52275604; called by muse, mutect2, varscan2
- CSMD3 | c.3058C>G p.R1020G (on ENST00000297405 / NM_001363185.1; = p.R916G on NM_052900.3) | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.258); catalogued as COSV99827650; called by muse, mutect2, varscan2
- CSN2 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); catalogued as COSV100778826; called by muse, mutect2, varscan2
- CSPG5 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53131454; called by muse, mutect2, varscan2
- CTNNA2 | c.2713T>C p.S905P (on ENST00000402739 / NM_001282597.3; = p.S857P on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.868); catalogued as rs757086633, COSV100561669; called by muse, mutect2, varscan2
- CTNND2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs1278093121, COSV58898815; called by muse, mutect2
- CUBN | c.6124G>A p.G2042R | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746491117; called by muse, mutect2, varscan2
- CUL3 | c.208G>T p.G70* | Nonsense Mutation (SNP) | VAF 15/116 reads (13%) | catalogued as COSV52368270; called by muse, mutect2, varscan2
- CYFIP1 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753341549; called by muse, mutect2, varscan2
- CYP1A1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.932); catalogued as rs375219443; called by muse, mutect2, varscan2
- CYP2F1 | c.1283C>A p.P428H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58527075; called by mutect2, varscan2
- DCDC1 | c.658G>C p.G220R | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100663334; called by muse, mutect2, varscan2
- DGKK | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV65709735; called by muse, mutect2, varscan2
- DKK2 | c.77C>A p.S26* | Nonsense Mutation (SNP) | VAF 31/249 reads (12%) | catalogued as COSV99569347; called by muse, mutect2, varscan2
- DMBT1 | c.1809G>T p.R603S | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as COSV57541721; called by mutect2, varscan2
- DNAAF4 | c.917A>G p.Y306C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs114329118; called by muse, mutect2
- DNAH3 | c.8813C>A p.A2938D | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.052); catalogued as COSV54527101; called by muse, mutect2, varscan2
- DOCK1 | c.4632C>T p.A1544= | Splice Region (SNP) | VAF 29/83 reads (35%) | catalogued as rs755587095; called by muse, mutect2, varscan2
- DPP3 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV100855407, COSV64756305; called by muse, mutect2, varscan2
- DTD1 | c.383G>C p.G128A | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV66281613; called by muse, mutect2, varscan2
- DUSP23 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 82/248 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63660472; called by muse, mutect2, varscan2
- EDRF1 | c.2625G>T p.L875F (on ENST00000356792 / NM_001202438.2; = p.L841F on NM_015608.2) | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1176875693; called by muse, mutect2, varscan2
- EML6 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62869325; called by muse, mutect2, varscan2
- EP400 | c.1675G>C p.G559R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.64); catalogued as COSV100200445, COSV100200737; called by muse, mutect2, varscan2
- EPB41L3 | c.1346G>T p.G449V | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs754128977; called by muse, mutect2, varscan2
- EPHA3 | c.2927C>A p.S976* | Nonsense Mutation (SNP) | VAF 25/109 reads (23%) | catalogued as COSV60727126; called by muse, mutect2, varscan2
- EPHB6 | c.245C>A p.P82Q | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.394); catalogued as COSV67420923; called by muse, mutect2, varscan2
- EREG | c.42G>T p.R14S | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.01); catalogued as rs1239604549; called by muse, mutect2, varscan2
- ESR1 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52786522; called by muse, mutect2, varscan2
- EXT1 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV65479902; called by muse, mutect2, varscan2
- F13A1 | c.232C>A p.R78S | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM023370, COSV53554575, COSV53565368; called by muse, mutect2, varscan2
- F8 | c.1573G>T p.G525* | Nonsense Mutation (SNP) | VAF 47/157 reads (30%) | catalogued as CM108711, CM1414972; called by muse, mutect2, varscan2
- F8 | c.906G>C p.Q302H | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.913); catalogued as CD961976; called by muse, varscan2
- FAM135B | c.3091G>T p.V1031L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs956298724; called by muse, mutect2, varscan2
- FAT3 | c.3045A>T p.K1015N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV53098300; called by muse, varscan2
- FBN3 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747885195; called by muse, mutect2, varscan2
- FBXL7 | c.314C>A p.S105Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as COSV61647016; called by muse, mutect2, varscan2
- FER1L6 | c.3815C>A p.P1272H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101205736; called by muse, mutect2, varscan2
- FEV | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773550327; called by muse, mutect2, varscan2
- FGF21 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV55810608; called by muse, varscan2
- FLG | c.6929C>A p.S2310Y | Missense Mutation (SNP) | VAF 282/450 reads (63%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); catalogued as COSV100911687, COSV64239386; called by muse, mutect2, varscan2
- FLG | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 371/669 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748125717; called by muse, mutect2, varscan2
- FLNC | c.7030G>T p.A2344S | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57956828; called by muse, mutect2, varscan2
- FMN2 | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV60429876, COSV60430635; called by muse, mutect2, varscan2
- FRMPD4 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV101043007; called by muse, mutect2, varscan2
- FRYL | c.6754C>T p.R2252C | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755564286; called by muse, mutect2, varscan2
- FSIP2 | c.12598G>C p.D4200H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV58098852; called by muse, mutect2, varscan2
- FUOM | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs749267993; called by muse, mutect2, varscan2
- GABRA4 | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV51924431; called by muse, mutect2, varscan2
- GABRA5 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59479875, COSV59479912; called by muse, mutect2, varscan2
- GALNT13 | c.517T>G p.L173V | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs765363190; called by muse, varscan2
- GAP43 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 80/170 reads (47%) | catalogued as COSV59348582; called by muse, mutect2, varscan2
- GCNT1 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as COSV65058625; called by muse, mutect2, varscan2
- GDF15 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99415999; called by muse, mutect2, varscan2
- GOLGA8O | c.591G>C p.Q197H | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs565343702; called by muse, mutect2, varscan2
- GPR89B | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as rs1409634730; called by muse, mutect2, varscan2
- GPRC6A | c.240C>A p.S80R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1333982207; called by muse, mutect2, varscan2
- GPRIN3 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.037); catalogued as COSV60886498; called by muse, mutect2, varscan2
- GRIA2 | c.573G>T p.M191I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52386581; called by muse, mutect2, varscan2
- GSX2 | c.232G>C p.A78P | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.15); catalogued as COSV104400791; called by muse, mutect2, varscan2
- HCN1 | c.2239C>A p.Q747K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV99079140; called by muse, mutect2, varscan2
- HCN1 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.357); catalogued as COSV100298381, COSV57492101, COSV57537055; called by muse, mutect2, varscan2
- HEATR5B | c.1870C>A p.H624N | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs764605370; called by muse, mutect2, varscan2
- HGF | c.1441G>C p.D481H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV55947201; called by muse, mutect2, varscan2
- HMCN2 | c.688C>A p.H230N | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.298); catalogued as rs980556251; called by muse, mutect2
- HUWE1 | c.5230G>C p.E1744Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.062); catalogued as COSV53338229; called by muse, mutect2, varscan2
- IFT122 | c.3154-4G>A | Splice Region (SNP) | VAF 39/133 reads (29%) | catalogued as rs1193130814; called by muse, mutect2, varscan2
- IGHV3-11 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as rs367668334; called by muse, mutect2, varscan2
- IGLV4-69 | c.145A>T p.S49C | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs775820038; called by muse, mutect2, varscan2
- IGSF22 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs201509265; called by muse, varscan2
- IL13RA2 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 15/125 reads (12%) | catalogued as COSV54563994; called by muse, mutect2, varscan2
- INHBA | c.575C>A p.A192D | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.213); catalogued as COSV54223288; called by muse, mutect2, varscan2
- INSYN2A | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as rs1223263750, COSV54731810; called by muse, mutect2, varscan2
- INSYN2B | c.914C>G p.S305C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.518); catalogued as COSV56972370; called by muse, mutect2, varscan2
- INSYN2B | c.685G>T p.V229L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99910037; called by muse, mutect2
- IPO8 | c.2353G>T p.V785F | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56244801; called by muse, mutect2, varscan2
- IQUB | c.301A>G p.M101V | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs777466154; called by muse, mutect2, varscan2
- IRAK3 | c.1115G>C p.R372T | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs763999725, COSV54166680; called by muse, mutect2, varscan2
- ISLR2 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.557); catalogued as COSV62301881; called by muse, mutect2, varscan2
- ITLN1 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 66/385 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs377093370; called by muse, mutect2, varscan2
- ITPR2 | c.7502G>A p.G2501E | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67269471, COSV67276318; called by muse, varscan2
- KASH5 | c.663G>A p.M221I | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1300479714; called by muse, mutect2
- KCNK6 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368898579; called by muse, mutect2, varscan2
- KEAP1 | c.995del p.G332Afs*68 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as COSV50480137, COSV99407912; called by mutect2, pindel, varscan2
- KHDRBS2 | c.1019del p.G340Dfs*17 | Frame Shift Del (DEL) | VAF 41/249 reads (16%) | catalogued as COSV55459640; called by mutect2, pindel, varscan2
- KIAA1755 | c.1741C>A p.L581M | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54076234; called by muse, mutect2, varscan2
- KIAA1755 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs746000428; called by muse, mutect2, varscan2
- KIF2B | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV52135668; called by muse, mutect2, varscan2
- KIFC3 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.245); catalogued as rs782177709, COSV65549648; called by mutect2, varscan2
- KIR3DL3 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV52545631, COSV99399929; called by muse, mutect2, varscan2
- KLHL30 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.086); catalogued as rs1007756444; called by muse, mutect2, varscan2
- KRTAP20-1 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 52/159 reads (33%) | PolyPhen probably damaging (0.954); catalogued as rs769908331, COSV58167811; called by muse, mutect2, varscan2
- KRTAP4-11 | c.436del p.R146Afs*101 | Frame Shift Del (DEL) | VAF 94/392 reads (24%) | catalogued as COSV66948487; called by pindel, varscan2
- KRTAP4-2 | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473798038; called by muse, varscan2
- KSR1 | c.772G>C p.G258R (on ENST00000644974 / NM_001367810.1; = p.G121R on NM_014238.2) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.986); catalogued as COSV99258464; called by mutect2, varscan2
- L1CAM | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100649030; called by muse, mutect2, varscan2
- LAMA2 | c.6225C>A p.S2075R | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV70343844; called by muse, mutect2
- LAMA4 | c.4420G>A p.G1474R (on ENST00000230538 / NM_001105206.3; = p.G1467R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57896525; called by muse, mutect2, varscan2
- LAMA4 | c.3879G>A p.M1293I (on ENST00000230538 / NM_001105206.3; = p.M1286I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs1554329600, COSV57898237, COSV57905568; called by muse, mutect2, varscan2
- LAMA5 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV53360309; called by muse, mutect2, varscan2
- LBHD1 | c.817G>A p.E273K (on ENST00000431002 / NM_001367940.1; = p.E247K on NM_024099.3) | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100649087; called by muse, varscan2
- LBHD1 | c.592C>T p.L198F (on ENST00000431002 / NM_001367940.1; = p.L172F on NM_024099.3) | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs752428625; called by muse, mutect2, varscan2
- LIN7A | c.201+1G>A p.X67_splice | Splice Site (SNP) | VAF 42/142 reads (30%) | catalogued as COSV99692237; called by muse, varscan2
- LRFN5 | c.922T>A p.C308S | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53244360; called by muse, mutect2, varscan2
- LRFN5 | c.1632C>A p.F544L | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325035617, COSV53269334; called by muse, mutect2, varscan2
- LRRC37B | c.1846C>T p.R616* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as rs1391577583, COSV100496386; called by muse, mutect2, varscan2
- LRRTM4 | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69141022; called by muse, mutect2, varscan2
- LZTR1 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV53148744; called by muse, mutect2, varscan2
- MAB21L1 | c.77C>G p.A26G | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100082915; called by muse, mutect2, varscan2
- MAGT1 | c.355G>T p.V119L (on ENST00000618282 / NM_001367916.1; = p.V151L on NM_032121.5) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100800451; called by muse, mutect2, varscan2
- MAP7D3 | c.2044G>T p.A682S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.401); catalogued as COSV60170230; called by muse, mutect2, varscan2
- MCF2 | c.2216G>T p.R739L | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV58483217; called by muse, mutect2, varscan2
- MDGA2 | c.2618C>A p.S873* (on ENST00000399232 / NM_001113498.2; = p.S575* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV62078415; called by muse, mutect2, varscan2
- MED12L | c.2180C>T p.T727I | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.098); catalogued as rs1255538927; called by muse, mutect2, varscan2
- MICOS13 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs757092651; called by muse, mutect2, varscan2
- MICU1 | c.1373A>G p.Q458R (on ENST00000361114 / NM_001195518.2; = p.Q464R on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769314310; called by muse, mutect2, varscan2
- MOCOS | c.2402G>T p.R801L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV54344649; called by muse, mutect2, varscan2
- MRC1 | c.2769G>T p.Q923H | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV53470466; called by muse, mutect2, varscan2
- MRC1 | c.2770C>T p.R924* | Nonsense Mutation (SNP) | VAF 31/286 reads (11%) | catalogued as rs782352494; called by muse, mutect2, varscan2
- MRGPRX4 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1216412746; called by muse, mutect2, varscan2
- MTCL1 | c.1405G>T p.A469S (on ENST00000306329 / NM_001378206.1; = p.A109S on NM_015210.4) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV60409455; called by muse, mutect2, varscan2
- MUC16 | c.16351C>A p.P5451T | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV67442968; called by muse, mutect2, varscan2
- MUC16 | c.2344C>A p.P782T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV67476217; called by muse, mutect2, varscan2
- MUC5B | c.126C>A p.G42= | Splice Region (SNP) | VAF 18/68 reads (26%) | catalogued as rs761751705, COSV71592186; called by muse, mutect2, varscan2
- MYF6 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV57353797; called by muse, mutect2, varscan2
- MYH1 | c.2995G>C p.E999Q | Missense Mutation (SNP) | VAF 49/320 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1380508250; called by muse, mutect2, varscan2
- MYH4 | c.4271G>T p.R1424M | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55124305; called by muse, mutect2, varscan2
- MYH8 | c.2171+1G>A p.X724_splice | Splice Site (SNP) | VAF 23/131 reads (18%) | catalogued as rs750636603; called by muse, mutect2, varscan2
- N4BP2 | c.372G>T p.E124D | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54700861; called by muse, mutect2
- NAB2 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1360300982; called by muse, mutect2, varscan2
- NCAN | c.2298C>A p.S766R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs143819093; called by muse, mutect2, varscan2
- NDN | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV100086442, COSV100086481; called by muse, mutect2, varscan2
- NEB | c.5214G>T p.K1738N | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99078003; called by muse, mutect2, varscan2
- NELFA | c.1257G>C p.Q419H (on ENST00000542778; = p.Q408H on NM_005663.5) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV99043927; called by muse, mutect2, varscan2
- NEMF | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53589871, COSV53591216; called by muse, mutect2, varscan2
- NFAT5 | c.4417A>G p.I1473V | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs753321494; called by muse, mutect2, varscan2
- NFIL3 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs748612574; called by muse, mutect2, varscan2
- NLE1 | c.549G>T p.W183C | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1362635267; called by muse, mutect2, varscan2
- NLGN4X | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1199804447; called by muse, mutect2, varscan2
- NLRP3 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 75/323 reads (23%) | catalogued as COSV60225054; called by muse, mutect2, varscan2
- NLRP7 | c.1946C>A p.T649N | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs1432726123; called by muse, mutect2, varscan2
- NLRP7 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751795513; called by muse, mutect2, varscan2
- NOL11 | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.296); catalogued as rs757607541, COSV99475009, COSV99475345; called by muse, mutect2
- NOS1AP | c.1427G>T p.R476L | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV100722907; called by muse, mutect2, varscan2
- NPNT | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59751974; called by muse, mutect2, varscan2
- NPY1R | c.387C>A p.F129L | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.741); catalogued as COSV56716362; called by muse, mutect2, varscan2
- NTM | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs145004908, COSV66205600; called by muse, mutect2, varscan2
- NTSR1 | c.634C>A p.R212S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as rs141293864; called by muse, mutect2, varscan2
- NUP155 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 103/308 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.432); catalogued as rs761630594; called by muse, mutect2, varscan2
- OCA2 | c.2200C>A p.L734M | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV100668055; called by muse, mutect2, varscan2
- OR10T2 | c.556A>T p.I186F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57782038; called by muse, mutect2, varscan2
- OR2C3 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as rs773436526, COSV63576554; called by muse, mutect2, varscan2
- OR2M5 | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs760060672; called by muse, mutect2, varscan2
- OR4A16 | c.60T>G p.D20E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59042201; called by muse, mutect2
- OR4C15 | c.920G>A p.C307Y (on ENST00000314644; = p.C253Y on NM_001001920.2) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs143375710, COSV100116111; called by muse, mutect2, varscan2
- OR4D6 | c.266G>T p.R89M | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV55659976; called by muse, mutect2
- OR4N5 | c.545del p.P182Hfs*17 | Frame Shift Del (DEL) | VAF 23/144 reads (16%) | catalogued as COSV61321343; called by mutect2, pindel, varscan2
- OR51B4 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV66517986; called by muse, varscan2
- OR52L1 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV59988796; called by muse, mutect2, varscan2
- OR56A3 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV61569098; called by muse, mutect2, varscan2
- OR56A3 | c.551C>A p.A184D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV61569605; called by muse, mutect2, varscan2
- OR5AS1 | c.368A>T p.Y123F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV99046975; called by muse, mutect2, varscan2
- OR5F1 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53547100; called by muse, mutect2, varscan2
- OR5W2 | c.819G>T p.M273I | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV60617889; called by muse, varscan2
- OSTM1 | c.402G>T p.G134= | Splice Region (SNP) | VAF 61/252 reads (24%) | catalogued as rs756543322; called by muse, mutect2, varscan2
- OTOA | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99625601; called by muse, mutect2, varscan2
- OTOF | c.1102G>T p.G368W | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM118015; called by muse, mutect2, varscan2
- OTOG | c.3098C>T p.S1033F | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs569953721; called by muse, mutect2, varscan2
- OTUD6A | c.677C>A p.S226* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100610997; called by muse, mutect2, varscan2
- OVCH1 | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as rs755429258; called by muse, mutect2, varscan2
- P3H2 | c.923A>G p.H308R | Missense Mutation (SNP) | VAF 125/268 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs879234801; called by muse, mutect2, varscan2
- PAH | c.1273G>T p.D425Y | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61020657; called by muse, mutect2, varscan2
- PAK5 | c.908C>A p.A303E | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs746868962, COSV62036542; called by muse, mutect2, varscan2
- PAPLN | c.1352G>T p.R451L (on ENST00000554301; = p.R424L on NM_173462.4) | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV53713724; called by muse, mutect2, varscan2
- PAX3 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 83/361 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV60586370; called by muse, mutect2, varscan2
- PBOV1 | c.257C>A p.T86K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.682); catalogued as rs755450557; called by muse, mutect2, varscan2
- PBRM1 | c.2876A>G p.H959R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs372395774; called by muse, mutect2, varscan2
- PCDH10 | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99994566; called by muse, mutect2, varscan2
- PCDHA4 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1554123890; called by muse, mutect2, varscan2
- PCDHB16 | c.1811A>C p.Y604S | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as rs781983602; called by muse, mutect2, varscan2
- PCDHGB5 | c.2043G>T p.Q681H | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs779918187, COSV53994863; called by muse, mutect2, varscan2
- PCOLCE | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.594); catalogued as rs755511553; called by muse, mutect2, varscan2
- PDE9A | c.497+1G>T p.X166_splice | Splice Site (SNP) | VAF 47/186 reads (25%) | catalogued as rs1336492782; called by muse, mutect2, varscan2
- PDZRN3 | c.2446G>T p.E816* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as rs1479470806, COSV55205659; called by muse, mutect2, varscan2
- PDZRN3 | c.2281G>T p.G761C | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189732803; called by muse, mutect2, varscan2
- PHF2 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100823085; called by muse, mutect2, varscan2
- PIEZO2 | c.6619G>T p.G2207C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53287531; called by mutect2, varscan2
- PIK3CG | c.3071C>A p.T1024K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as COSV63246204; called by muse, mutect2, varscan2
- PKD1L3 | c.1803C>A p.H601Q | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs537040106, COSV58664953; called by muse, mutect2, varscan2
- PKLR | c.823G>T p.G275W | Missense Mutation (SNP) | VAF 66/463 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM950947, CM971208, COSV61361113; called by muse, mutect2, varscan2
- PLB1 | c.2875G>A p.V959M | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs759537881, COSV59828834; called by muse, mutect2, varscan2
- PLCXD3 | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.745); catalogued as COSV60606473; called by muse, mutect2
- PLXNA3 | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.072); catalogued as rs368644346, COSV63754384; called by muse, mutect2, varscan2
- PML | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 28/175 reads (16%) | catalogued as COSV51446859; called by muse, mutect2, varscan2
- POPDC2 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 93/227 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99951120; called by muse, mutect2, varscan2
- PPHLN1 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 43/224 reads (19%) | catalogued as rs764149372; called by muse, mutect2, varscan2
- PPP6R1 | c.1945C>T p.Q649* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as rs1279021412; called by muse, mutect2, varscan2
- PRDM14 | c.1450T>A p.S484T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.568); catalogued as rs770009110; called by muse, mutect2, varscan2
- PRF1 | c.1154G>T p.R385L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs781476866, COSV64614500; called by muse, mutect2, varscan2
- PRKACG | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs776449361; called by muse, mutect2
- PRKN | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.967); catalogued as COSV58239542, COSV58258013; called by muse, mutect2, varscan2
- PRMT9 | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs145625390; called by muse, mutect2, varscan2
- PTER | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.217); catalogued as rs747439017; called by muse, mutect2, varscan2
- PTH1R | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs959937327; called by muse, mutect2, varscan2
- PTPRD | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV61960935; called by muse, mutect2, varscan2
- PTPRJ | c.1226C>G p.S409C | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.928); catalogued as rs763129111; called by muse, mutect2, varscan2
- PTPRK | c.835G>T p.G279C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63888307; called by muse, mutect2, varscan2
- PYGB | c.2079G>A p.M693I | Missense Mutation (SNP) | VAF 75/256 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV99405393; called by muse, mutect2, varscan2
- PYGL | c.663G>T p.V221= | Splice Region (SNP) | VAF 22/88 reads (25%) | catalogued as rs370565099, COSV99368450; called by muse, mutect2, varscan2
- PYGM | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as rs536561941, COSV51230764; called by muse, mutect2, varscan2
- QRFPR | c.821T>C p.M274T | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1483553746; called by muse, mutect2, varscan2
- RBMXL3 | c.2237G>T p.R746L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.25); catalogued as rs201047008, COSV57746199; called by muse, mutect2, varscan2
- REST | c.2930C>T p.S977L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1336617929, COSV58359673; called by muse, mutect2, varscan2
- RGS6 | c.51G>T p.E17D | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as rs1465474688; called by muse, mutect2, varscan2
- RGS7 | c.846-1G>A p.X282_splice | Splice Site (SNP) | VAF 28/107 reads (26%) | catalogued as COSV58558303; called by muse, mutect2, varscan2
- RHOXF2 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 105/605 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.021); catalogued as COSV101002786; called by muse, mutect2, varscan2
- RIN3 | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as rs759963039; called by muse, mutect2, varscan2
- ROR2 | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious, low confidence (0); catalogued as COSV65244715; called by muse, mutect2, varscan2
- RTL4 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV100465881, COSV61205874; called by muse, mutect2
- RYR2 | c.7429G>T p.G2477W | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63686351; called by muse, mutect2, varscan2
- RYR2 | c.7430G>T p.G2477V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63672668; called by muse, mutect2, varscan2
- RYR2 | c.12719C>T p.T4240M | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV63714535; called by muse, varscan2
- SATB2 | c.1951C>G p.Q651E | Missense Mutation (SNP) | VAF 70/367 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53483325, COSV99612930; called by muse, mutect2, varscan2
- SCGB2B2 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV64857055; called by muse, mutect2, varscan2
- SCN5A | c.5168C>A p.T1723N (on ENST00000333535 / NM_198056.3; = p.T1722N on NM_000335.5) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.295); catalogued as rs199473300, CM097683; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- SCN9A | c.4142G>C p.R1381P (on ENST00000303354; = p.R1370P on NM_002977.3) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.788); catalogued as COSV57606262; called by muse, mutect2, varscan2
- SDHAP2 | n.903A>G | Splice Region (SNP) | VAF 90/677 reads (13%) | catalogued as rs764183000; called by muse, varscan2
- SEC24B | c.2653G>T p.A885S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.639); catalogued as rs373550185; called by muse, mutect2
- SEMA3F | c.1765G>A p.V589I | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.026); catalogued as rs752403483; called by muse, mutect2, varscan2
- SEMA6D | c.2585A>T p.K862M (on ENST00000316364 / NM_153618.2; = p.K800M on NM_020858.2) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as COSV60375793; called by muse, mutect2, varscan2
- SERPINA4 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.397); catalogued as rs1278033042, COSV54069426; called by muse, mutect2
- SERPING1 | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1362220560; called by muse, mutect2, varscan2
- SHLD2 | c.1583G>A p.S528N | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs756184116; called by muse, mutect2, varscan2
- SHOX | c.517C>A p.R173S | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM011486, COSV61862044; called by muse, mutect2, varscan2
- SHPRH | c.3833G>T p.G1278V (on ENST00000275233 / NM_001042683.3; = p.G1282V on NM_173082.3) | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768982387; called by muse, mutect2, varscan2
- SLC15A2 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1286522851, COSV55200884; called by muse, mutect2, varscan2
- SLC2A2 | c.562C>T p.L188F | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.044); catalogued as rs748052042; called by muse, mutect2, varscan2
- SLC35A3 | c.*560G>T | Splice Region (SNP) | VAF 11/31 reads (35%) | catalogued as COSV64516556; called by muse, mutect2, varscan2
- SLC37A1 | c.1586+1G>T p.X529_splice | Splice Site (SNP) | VAF 44/156 reads (28%) | catalogued as COSV61401216; called by muse, mutect2, varscan2
- SLC44A5 | c.1641G>T p.L547F | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs764447076; called by muse, mutect2, varscan2
- SLC45A2 | c.1036G>T p.V346L | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1350569256; called by muse, mutect2, varscan2
- SLC46A3 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs181221290; called by muse, mutect2, varscan2
- SLC5A5 | c.1524C>G p.P508= | Splice Region (SNP) | VAF 22/70 reads (31%) | catalogued as COSV99714700; called by muse, mutect2, varscan2
- SLC9A3 | c.932C>G p.A311G | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM1512085; called by muse, mutect2
- SLCO1B1 | c.915G>C p.K305N | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV57016831; called by muse, mutect2, varscan2
- SLITRK2 | c.64C>A p.R22S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.501); catalogued as COSV100158069, COSV59424087; called by muse, mutect2
- SMARCA4 | c.3485G>C p.G1162A | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60811919; called by muse, mutect2, varscan2
- SMOC2 | c.187C>A p.R63S | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.56); catalogued as COSV62440425; called by muse, mutect2, varscan2
- SPTA1 | c.2898G>T p.Q966H | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV63750156; called by muse, varscan2
- SPTB | c.6277G>A p.E2093K | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.216); catalogued as rs1328912901; called by muse, mutect2, varscan2
- SPTB | c.3172G>T p.G1058W | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV67631534; called by muse, mutect2, varscan2
- SPTBN5 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV58027153; called by muse, mutect2, varscan2
- SSH2 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV104393186; called by muse, mutect2, varscan2
- STON2 | c.2150G>T p.R717L (on ENST00000649389 / NM_001366849.2; = p.R660L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50842334; called by muse, mutect2, varscan2
- STPG2 | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.019); catalogued as COSV99759761; called by muse, mutect2, varscan2
- STXBP5 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.313); catalogued as COSV51648713; called by muse, mutect2, varscan2
- STXBP5 | c.431G>T p.R144M | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51648727; called by muse, mutect2, varscan2
- SULT1E1 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV56947926; called by muse, mutect2, varscan2
- SYCP3 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV57149249; called by muse, mutect2, varscan2
- SYK | c.1834G>T p.D612Y | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV65327255; called by muse, mutect2, varscan2
- SYNE2 | c.10303G>T p.D3435Y | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs931738357; called by muse, mutect2
- SYT5 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1176712345; called by muse, mutect2, varscan2
- SZT2 | c.5168C>T p.A1723V (on ENST00000634258 / NM_001365999.1; = p.A1666V on NM_015284.4) | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1473283422; called by muse, mutect2, varscan2
- TANC1 | c.3565G>T p.G1189C | Missense Mutation (SNP) | VAF 76/269 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755826547; called by muse, mutect2, varscan2
- TBX5 | c.215C>G p.T72R | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM157843; called by muse, mutect2, varscan2
- TBXT | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51617503; called by muse, mutect2
- TCF4 | c.1246G>T p.G416W | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV100610426; called by muse, mutect2, varscan2
- TENM1 | c.1288C>A p.L430M | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV100949418; called by muse, mutect2, varscan2
- TENM3 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as COSV69299546; called by muse, mutect2, varscan2
- TEPSIN | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs143078481; called by muse, mutect2, varscan2
- TEX13C | c.1049C>A p.P350Q | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV70114374; called by muse, mutect2, varscan2
- TEX26 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs754014952; called by muse, mutect2, varscan2
- TEX47 | c.352G>T p.V118F | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs767449422; called by muse, mutect2, varscan2
- TFAP2B | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV99539524; called by muse, mutect2, varscan2
- TMC3 | c.1622G>A p.W541* | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | catalogued as rs1344982621; called by muse, mutect2, varscan2
- TMC5 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as COSV66867996; called by muse, mutect2, varscan2
- TMEM121B | c.1023C>G p.I341M | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs768066373, COSV100083413; called by muse, mutect2, varscan2
- TMEM132B | c.854C>A p.S285* | Nonsense Mutation (SNP) | VAF 14/170 reads (8%) | catalogued as COSV54747299; called by muse, mutect2
- TMEM170A | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV100713181; called by muse, mutect2, varscan2
- TMEM260 | c.1489A>G p.I497V | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376435235; called by muse, mutect2, varscan2
- TMEM68 | c.198C>A p.H66Q | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1184240617; called by muse, mutect2, varscan2
- TNN | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.071); catalogued as COSV53429565; called by muse, mutect2, varscan2
- TNR | c.1931del p.G644Afs*10 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as COSV99688494; called by pindel, varscan2
- TRAF4 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as rs754546702; called by muse, mutect2, varscan2
- TRGC2 | c.429T>A p.D143E | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.198); catalogued as rs1218384473; called by muse, mutect2, varscan2
- TRPA1 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs759879377, COSV51566671; called by muse, mutect2, varscan2
- TRPA1 | c.690G>C p.L230F | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV51559581; called by muse, varscan2
- TSHR | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 79/339 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV99992580; called by muse, mutect2, varscan2
- TSSC4 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770569974; called by muse, mutect2, varscan2
- TTN | c.34847C>A p.A11616E (on ENST00000591111; = p.A10689E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | PolyPhen benign (0); catalogued as COSV60234178; called by muse, mutect2, varscan2
- TUBD1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs1444280305; called by muse, mutect2, varscan2
- UACA | c.498C>T p.D166= | Splice Region (SNP) | VAF 12/62 reads (19%) | catalogued as rs575135370; called by muse, varscan2
- UBE2D1 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV64219049; called by muse, mutect2, varscan2
- UBXN1 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV53658195; called by muse, mutect2, varscan2
- UGT2A3 | c.1349A>C p.Q450P | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52359634; called by muse, mutect2
- UNC45A | c.2313C>G p.I771M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs780133821; called by muse, mutect2, varscan2
- UNC5B | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.714); catalogued as rs1214447988, COSV58975215; called by mutect2, varscan2
- UNC80 | c.1086G>T p.M362I | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55892952; called by muse, mutect2, varscan2
- UNC80 | c.1874C>A p.S625Y | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55905918; called by muse, mutect2, varscan2
- UNC80 | c.3754G>T p.G1252* | Nonsense Mutation (SNP) | VAF 54/280 reads (19%) | catalogued as COSV55888455; called by muse, mutect2, varscan2
- UNK | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53139266; called by muse, mutect2, varscan2
- USP10 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs758198904; called by muse, mutect2, varscan2
- USP17L7 | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 64/262 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.322); catalogued as rs773257019; called by muse, mutect2, varscan2
- USP34 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as rs1317764083; called by muse, mutect2, varscan2
- VWA3A | c.2432C>T p.T811I | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.07); catalogued as COSV55393260; called by muse, mutect2, varscan2
- WDR72 | c.452G>T p.R151I | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV64742229; called by muse, mutect2, varscan2
- YTHDC2 | c.1613C>G p.S538* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | catalogued as COSV99362977, COSV99363041; called by muse, mutect2, varscan2
- ZFAND4 | c.1924G>A p.V642I | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs768754689; called by muse, mutect2, varscan2
- ZFHX4 | c.3919G>A p.D1307N | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.623); catalogued as COSV50481490, COSV51477651; called by muse, varscan2
- ZFHX4 | c.7718C>T p.T2573M | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs767006421; called by muse, mutect2, varscan2
- ZFP62 | c.1657C>G p.R553G (on ENST00000502412 / NM_001377944.1; = p.R520G on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs897936540, COSV100772736; called by muse, mutect2, varscan2
- ZFPM2 | c.1705C>A p.H569N | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.995); catalogued as COSV65873261; called by muse, mutect2, varscan2
- ZNF112 | c.2509G>T p.V837L (on ENST00000337401 / NM_001083335.2; = p.V831L on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV100495602; called by muse, mutect2, varscan2
- ZNF197 | c.2048G>T p.C683F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998106665; called by muse, mutect2, varscan2
- ZNF208 | c.3334C>A p.P1112T | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769480170; called by muse, mutect2, varscan2
- ZNF208 | c.2420G>T p.C807F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV68107829; called by muse, mutect2, varscan2
- ZNF333 | c.1379A>G p.N460S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as rs1166675099; called by muse, mutect2, varscan2
- ZNF408 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs1284031600; called by muse, mutect2, varscan2
- ZNF492 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as rs1354273709; called by mutect2, varscan2
- ZNF536 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV62819722; called by muse, mutect2, varscan2
- ZNF711 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 21/98 reads (21%) | catalogued as COSV52157879; called by muse, mutect2, varscan2
- ZNF729 | c.1997G>T p.S666I | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.853); catalogued as COSV62605578; called by muse, varscan2
- ZP4 | c.1109C>A p.T370K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100850797; called by muse, varscan2
- AASS | c.2721A>G p.I907M | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ABCA12 | c.1387C>G p.L463V (on ENST00000272895 / NM_173076.3; = p.L145V on NM_015657.3) | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ABCA4 | c.6474G>T p.K2158N | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ABCA6 | c.4764G>C p.E1588D | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCB9 | c.1332C>G p.N444K | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ABCC9 | c.651del p.Q217Hfs*4 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel, varscan2
- ABCG1 | c.735-2A>T p.X245_splice | Splice Site (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- AC011455.2 | c.1486A>T p.T496S | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- AC244258.1 | n.624-2A>T | Splice Site (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- ACSM2A | c.1377G>T p.M459I (on ENST00000219054; = p.M380I on NM_001308169.2) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, varscan2
- ACSM5 | c.1657-6C>G | Splice Region (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- ACTR3B | c.1063G>T p.G355C | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ACVR1 | c.455G>C p.R152P | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- ADAM11 | c.1194G>T p.W398C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAM33 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ADAMTS1 | c.2621G>T p.W874L | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS17 | c.424A>T p.S142C | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS18 | c.991del p.D331Mfs*8 | Frame Shift Del (DEL) | VAF 16/141 reads (11%) | called by mutect2, pindel
- ADAMTS20 | c.2711G>T p.C904F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMTS20 | c.2710T>C p.C904R | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS20 | c.2551G>T p.D851Y | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADAMTS4 | c.2335C>A p.Q779K | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY10 | c.3955G>A p.G1319S | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADCY2 | c.560T>A p.L187Q | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- ADCY2 | c.2746_2748delinsTT p.N917Tfs*35 | Frame Shift Del (DEL) | VAF 24/129 reads (19%) | called by pindel, varscan2*
- ADCY7 | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADCY8 | c.2721G>T p.M907I | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- ADGB | c.613-1G>A p.X205_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- ADGRD1 | c.2436+7C>T | Splice Region (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2
- ADGRD2 | c.2298G>T p.M766I | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ADRA2C | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AFF2 | c.29G>T p.W10L | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFF3 | c.129T>A p.D43E | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- AGBL2 | c.1891T>A p.S631T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AGPAT4 | c.420G>T p.E140D | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AGPS | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGTR1 | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- AHNAK2 | c.12562G>T p.A4188S | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- AK3 | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- AKAP6 | c.1942del p.E648Kfs*3 | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | called by mutect2, varscan2
- AKR1B1 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 154/375 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- AL021368.4 | n.219+1G>T | Splice Site (SNP) | VAF 13/113 reads (12%) | called by mutect2, varscan2
- AL096814.1 | c.205A>G p.K69E | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- AL592490.1 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AL592490.1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- ALOX15 | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALOX5 | c.558G>T p.M186I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALOXE3 | c.2059C>T p.Q687* | Nonsense Mutation (SNP) | VAF 44/139 reads (32%) | called by muse, mutect2, varscan2
- ALPK2 | c.1640A>T p.K547M | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ALX1 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ANGPT4 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKEF1 | c.2248G>C p.V750L | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- ANKRD17 | c.3289G>T p.E1097* | Nonsense Mutation (SNP) | VAF 47/237 reads (20%) | called by muse, mutect2, varscan2
- ANKRD30B | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- ANKRD30B | c.1480G>T p.G494W | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); called by muse, varscan2
- ANKRD30B | c.3838C>A p.H1280N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD31 | c.5096T>A p.I1699K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ANKRD34C | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ANKRD42 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ANKUB1 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ANLN | c.395C>G p.S132* | Nonsense Mutation (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- ANO7 | c.110G>C p.R37T | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- AOC1 | c.82dup p.R28Kfs*61 | Frame Shift Ins (INS) | VAF 42/122 reads (34%) | called by mutect2, pindel, varscan2
- AP002512.3 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- APCS | c.419A>G p.Q140R | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APOB | c.3664A>G p.T1222A | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- AR | c.990C>A p.S330R | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.474); called by muse, varscan2
- ARFGEF1 | c.735A>T p.Q245H | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP42 | c.2561G>T p.W854L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARHGEF10 | c.2463-1G>T p.X821_splice (on ENST00000398564; = p.X796_splice on NM_014629.4) | Splice Site (SNP) | VAF 37/156 reads (24%) | called by muse, varscan2
- ARHGEF10 | c.3471A>T p.P1157= (on ENST00000398564; = p.P1132= on NM_014629.4) | Splice Region (SNP) | VAF 42/174 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF26 | c.2088G>T p.K696N | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF4 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ARID1A | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- ARID1A | c.6711_6712del p.L2238Afs*39 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | called by pindel, varscan2
- ARMH4 | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- ARR3 | c.768-1G>A p.X256_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | called by mutect2, varscan2
- ATE1 | c.1516G>T p.G506W | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATF6 | c.1615G>T p.G539W | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ATP10A | c.2953A>G p.K985E | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ATP2B3 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ATP6AP1 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ATP7A | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ATRNL1 | c.929C>A p.A310E | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- ATRX | c.1253G>T p.R418L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AWAT1 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- BAIAP3 | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- BAZ2A | c.4973G>A p.C1658Y | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- BAZ2A | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BCHE | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCL2L12 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- BCORL1 | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- BEND2 | c.326dup p.H109Qfs*7 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel, varscan2
- BICC1 | c.2262dup p.T755Hfs*11 | Frame Shift Ins (INS) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- BIRC6 | c.5917G>C p.A1973P | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- BMT2 | c.686C>G p.P229R | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- BOD1L1 | c.7700C>A p.T2567N | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BOD1L1 | c.4838G>T p.G1613V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BPIFC | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BPNT1 | c.340G>T p.V114F | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- BRCC3 | c.860T>A p.L287* | Nonsense Mutation (SNP) | VAF 64/210 reads (30%) | called by muse, mutect2, varscan2
- BSG | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by mutect2, varscan2
- BTK | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- C11orf87 | c.288G>T p.R96S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- C11orf98 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 17/170 reads (10%) | called by muse, varscan2
- C12orf50 | c.1055G>C p.R352P | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- C16orf89 | c.1150C>A p.L384I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- C19orf84 | c.402G>T p.R134S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- C1QTNF4 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- C1orf194 | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C1orf94 | c.863C>A p.P288Q (on ENST00000488417 / NM_001134734.2; = p.P98Q on NM_032884.5) | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- C4orf54 | c.5314G>T p.G1772W | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C8orf34 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated, low confidence (0.09); called by mutect2, varscan2
- C9orf24 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- CA5A | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CA7 | c.114C>A p.S38R | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1S | c.2536G>T p.E846* | Nonsense Mutation (SNP) | VAF 65/280 reads (23%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNG6 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CADM3 | c.636C>G p.N212K (on ENST00000368125 / NM_001127173.3; = p.N246K on NM_021189.5) | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, varscan2
- CALCRL | c.436A>T p.I146L | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CAPN1 | c.1942G>C p.G648R | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CARMIL1 | c.592del p.D198Ifs*10 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- CCDC136 | c.1577del p.P526Rfs*18 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | called by mutect2, pindel, varscan2
- CCDC168 | c.16492G>C p.E5498Q | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CCDC168 | c.15004A>G p.K5002E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CCDC168 | c.2345A>G p.E782G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- CCDC7 | c.2396T>A p.V799E | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.135); called by muse, varscan2
- CCKAR | c.773C>A p.T258N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0); called by mutect2, varscan2
- CCL17 | c.119del p.G40Efs*8 | Frame Shift Del (DEL) | VAF 54/164 reads (33%) | called by mutect2, pindel, varscan2
- CCR6 | c.941del p.V314Gfs*15 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | called by mutect2, varscan2
- CCS | c.664G>C p.G222R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CD99L2 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDH12 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH2 | c.2515-1G>T p.X839_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2
- CDH23 | c.2279G>T p.G760V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- CDK5RAP3 | c.925G>T p.G309W | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CEACAM20 | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 65/251 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CELSR2 | c.7562G>T p.W2521L | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPE | c.5523G>T p.E1841D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2
- CENPF | c.3974G>T p.R1325M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CENPS | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CEP295NL | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CERS3 | c.427T>A p.L143I | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- CES2 | c.982G>C p.A328P | Missense Mutation (SNP) | VAF 128/274 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CFAP46 | c.4582G>T p.V1528L | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CFAP47 | c.9450G>T p.K3150N | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- CFTR | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 123/265 reads (46%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- CHAT | c.793G>T p.G265W | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CHIT1 | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.36); called by muse, mutect2
- CHL1 | c.1282A>T p.K428* (on ENST00000397491 / NM_001253387.1; = p.K444* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- CHM | c.1241G>T p.R414I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- CHRNA4 | c.501C>A p.F167L | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2
- CLCN5 | c.1713A>T p.E571D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLEC12B | c.409+1G>T p.X137_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | called by mutect2, varscan2
- CLEC4E | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CLIC3 | c.118dup p.T40Nfs*29 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- CLIC5 | c.541-1G>T p.X181_splice (on ENST00000185206 / NM_001370649.1; = p.X22_splice on NM_016929.5) | Splice Site (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- CLTCL1 | c.4648G>T p.A1550S (on ENST00000427926 / NM_007098.4; = p.A1493S on NM_001835.4) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CLVS1 | c.1006C>A p.L336M | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CMC1 | c.128A>T p.K43M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CMTM2 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 91/191 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CNBD1 | c.887A>T p.K296M | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CNGB3 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CNGB3 | c.98C>A p.P33Q | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CNOT1 | c.5029G>T p.D1677Y | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CNTLN | c.62G>T p.R21M | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CNTN5 | c.2338G>T p.V780L | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- COG4 | c.1297A>T p.R433W | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL11A1 | c.2131C>A p.P711T | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL15A1 | c.2464G>A p.V822M | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COL17A1 | c.4441G>A p.D1481N | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- COL17A1 | c.986C>A p.T329N | Missense Mutation (SNP) | VAF 97/273 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- COL6A2 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A2 | c.1459G>T p.G487* | Nonsense Mutation (SNP) | VAF 63/229 reads (28%) | called by muse, mutect2, varscan2
- COL6A3 | c.5198C>A p.P1733H | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- COL6A3 | c.67A>T p.T23S | Missense Mutation (SNP) | VAF 67/314 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- COLEC12 | c.883G>C p.G295R | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- COLEC12 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 31/195 reads (16%) | called by muse, mutect2, varscan2
- CPNE3 | c.426G>T p.L142F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.396); called by muse, varscan2
- CPSF1 | c.1243-6T>A | Splice Region (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- CPXCR1 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.552); called by muse, varscan2
- CRB2 | c.1164G>T p.W388C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CREBRF | c.1035G>C p.L345F | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CRISPLD1 | c.989A>T p.Y330F | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRLF3 | c.616T>C p.F206L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CRNKL1 | c.1766T>A p.L589Q | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CSMD2 | c.8866G>T p.G2956W | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD3 | c.547G>T p.V183F | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- CST11 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CST8 | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CTNNA2 | c.1469A>T p.E490V | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- CTNNAL1 | c.1883A>T p.E628V | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUBN | c.4433C>G p.S1478C | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CUBN | c.3647C>A p.P1216Q | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- CUX1 | c.473A>T p.E158V (on ENST00000292535 / NM_181552.4; = p.E169V on NM_001913.5) | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CWC22 | c.2093G>T p.S698I | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- CWC25 | c.547A>T p.K183* | Nonsense Mutation (SNP) | VAF 28/104 reads (27%) | called by muse, varscan2
- CYB5R4 | c.1173A>C p.E391D | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- CYB5R4 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CYFIP1 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- CYS1 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 78/303 reads (26%) | called by muse, mutect2, varscan2
- CYTH3 | c.661A>T p.M221L | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DCAF15 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DCDC1 | c.2854G>T p.V952F (on ENST00000597505 / NM_001367979.1; = p.V59F on NM_020869.3) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX60 | c.4299G>T p.M1433I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGKZ | c.2450G>T p.R817L (on ENST00000454345 / NM_001105540.2; = p.R629L on NM_003646.4) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- DHTKD1 | c.305C>A p.T102K | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- DHX38 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 93/241 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- DHX38 | c.1449G>T p.K483N | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DLG3 | c.1480G>T p.G494W (on ENST00000374360 / NM_021120.4; = p.G157W on NM_020730.3) | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLG4 | c.381G>T p.E127D (on ENST00000399506 / NM_001321075.3; = p.E170D on NM_001365.4) | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DLGAP3 | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- DMD | c.9023A>T p.Q3008L | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- DMRTC2 | c.197G>T p.C66F | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAAF3 | c.822G>T p.W274C (on ENST00000524407 / NM_001256715.2; = p.W321C on NM_178837.4) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAAF3 | c.821G>T p.W274L (on ENST00000524407 / NM_001256715.2; = p.W321L on NM_178837.4) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- DNAH10 | c.8295G>T p.L2765= (on ENST00000409039; = p.L2704= on NM_207437.3) | Splice Region (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- DNAH11 | c.11471C>A p.T3824N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); called by muse, mutect2
- DNAH6 | c.10756G>T p.V3586F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- DNAI3 | c.523A>T p.T175S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAJA2 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- DNAJC15 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); called by muse, mutect2
- DOC2B | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK1 | c.4582G>T p.G1528C | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK2 | c.3776C>A p.A1259E | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DOHH | c.56A>G p.Q19R | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOK6 | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- DOK7 | c.738C>A p.S246R | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DPY30 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DPYSL5 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2
- DRD5 | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DRD5 | c.1259C>G p.P420R | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DRP2 | c.2684C>A p.P895Q | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- DSCAML1 | c.3220C>A p.L1074M (on ENST00000321322; = p.L1014M on NM_020693.4) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- DSG3 | c.299T>C p.F100S | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSP | c.6766G>T p.G2256C | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTNA | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DUOX1 | c.2932G>C p.E978Q | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DUOX1 | c.3824T>C p.I1275T | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- DUSP4 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- DZIP3 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.373); called by muse, varscan2
- EBF3 | c.1217C>A p.A406E (on ENST00000355311 / NM_001375392.1; = p.A397E on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- ECPAS | c.3512G>T p.R1171L | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDEM2 | c.498G>T p.Q166H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); called by muse, mutect2
- EEF1A2 | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EFCAB6 | c.4308G>T p.W1436C | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EGFLAM | c.1894C>A p.L632I | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EGR4 | c.344C>A p.A115E (on ENST00000545030; = p.A12E on NM_001965.4) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- EIF4A3 | c.1049T>A p.I350N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ELFN1 | c.765C>A p.Y255* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | called by mutect2, varscan2
- EMILIN1 | c.1655C>A p.T552K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- EML5 | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENOX2 | c.461T>A p.I154N (on ENST00000338144 / NM_001382520.1; = p.I125N on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ENTPD7 | c.329A>T p.H110L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- EP300 | c.4537C>G p.L1513V | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPM2AIP1 | c.1276A>T p.I426F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- EPPK1 | c.2354G>T p.C785F | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERBB3 | c.437dup p.V147Cfs*4 | Frame Shift Ins (INS) | VAF 33/154 reads (21%) | called by mutect2, pindel, varscan2
- ERVH48-1 | c.281T>A p.V94E | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ESRRG | c.854A>G p.H285R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- EVC2 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EZH2 | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- F2 | c.449C>A p.A150D | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- F2 | c.1350C>A p.H450Q | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F8 | c.3110C>A p.P1037Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- FAM120C | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); called by muse, varscan2
- FAM122B | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM135B | c.2518C>A p.Q840K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAM172A | c.944C>G p.T315S | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FAM200B | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- FAM205A | c.3874C>A p.P1292T | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- FAM47C | c.1985G>C p.R662P | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, varscan2
- FAM53C | c.1074G>C p.E358D | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- FAM71D | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM90A1 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM98B | c.217G>T p.G73* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- FAT4 | c.5442dup p.R1815Sfs*3 | Frame Shift Ins (INS) | VAF 41/215 reads (19%) | called by mutect2, pindel, varscan2
- FAT4 | c.6044A>C p.N2015T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- FAT4 | c.14623G>T p.V4875F | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FBN2 | c.8715G>T p.M2905I | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN3 | c.5096A>G p.Y1699C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXL7 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- FGD1 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FGD1 | c.184G>C p.G62R | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FILIP1L | c.1452C>A p.F484L (on ENST00000354552 / NM_182909.3; = p.F244L on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/184 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG | c.11056G>T p.G3686W | Missense Mutation (SNP) | VAF 181/575 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLRT3 | c.1642G>T p.V548L | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- FMN1 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- FOLH1 | c.1357G>T p.D453Y | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXD4L4 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 50/680 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); called by muse, mutect2
- FREM3 | c.2691C>A p.N897K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FRG2C | c.256+1G>T p.X86_splice | Splice Site (SNP) | VAF 66/426 reads (15%) | called by muse, mutect2, varscan2
- FRK | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- FSHR | c.1847C>A p.P616H | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FUCA2 | c.1037C>G p.S346C | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); called by muse, varscan2
- FYB1 | c.1072C>A p.P358T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- FZD4 | c.689G>A p.C230Y | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- G6PC | c.390G>T p.M130I | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GALC | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- GALNT2 | c.872G>T p.R291M | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- GALNTL6 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATB | c.328-1G>C p.X110_splice | Splice Site (SNP) | VAF 12/32 reads (38%) | called by muse, varscan2
- GDF10 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDF7 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- GIMAP1 | c.704G>C p.G235A | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GIT2 | c.767G>T p.S256I (on ENST00000355312 / NM_057169.5; = p.S258I on NM_014776.5) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- GLG1 | c.2437-2A>T p.X813_splice | Splice Site (SNP) | VAF 54/114 reads (47%) | called by muse, mutect2, varscan2
- GLRA1 | c.799T>C p.W267R | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLUD1 | c.1076T>C p.L359P | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GNAS | c.718+3A>T | Splice Region (SNP) | VAF 121/501 reads (24%) | called by muse, mutect2, varscan2
- GNE | c.637G>T p.G213C (on ENST00000396594 / NM_001128227.3; = p.G182C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGA1 | c.847A>T p.T283S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.039); called by muse, mutect2
- GOLGA8M | c.1882C>A p.P628T | Missense Mutation (SNP) | VAF 42/281 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- GOLIM4 | c.262+2del p.X88_splice | Splice Site (DEL) | VAF 32/96 reads (33%) | called by mutect2, pindel*, varscan2
- GON4L | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 44/198 reads (22%) | called by muse, mutect2, varscan2
- GON4L | c.831G>T p.L277F | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPM6A | c.664G>T p.G222W | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GPR12 | c.535T>G p.W179G | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GPR137B | c.77A>T p.N26I | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- GPR52 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- GPR55 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- GPR78 | c.496C>G p.R166G | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPRASP1 | c.2969G>C p.G990A | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM3 | c.2462C>A p.P821H | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRWD1 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GSK3B | c.613A>T p.K205* | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- H2AC11 | c.119A>T p.Y40F | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- HAS1 | c.922C>A p.P308T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HCN1 | c.840A>T p.Q280H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- HDAC2 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HDAC9 | c.1512A>T p.E504D | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HELB | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- HERC2 | c.4371A>T p.L1457F | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HIC2 | c.1592G>T p.R531L | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- HIF1A | c.947G>C p.W316S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HIRA | c.1902G>T p.E634D | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HIVEP2 | c.320A>T p.Q107L | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- HLA-C | c.617_618del p.A206Gfs*14 | Frame Shift Del (DEL) | VAF 16/118 reads (14%) | called by pindel, varscan2
- HMCN1 | c.339+1G>T p.X113_splice | Splice Site (SNP) | VAF 55/181 reads (30%) | called by muse, mutect2, varscan2
- HMCN2 | c.4701G>C p.K1567N | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- HMGN5 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HMX1 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- HNRNPK | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- HNRNPUL1 | c.649A>T p.N217Y | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HOXC9 | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HPD | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- HSPA13 | c.376A>C p.K126Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.241); called by muse, mutect2
- HTR3E | c.490C>G p.L164V (on ENST00000415389 / NM_001256613.1; = p.L179V on NM_182589.2) | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
1,205 further variants in this file (569 protein-altering or splice-affecting, 402 silent, 234 other) are not listed here.
